Somatic mutation profile of tumor specimen TCGA-L5-A43C-01A (aliquot TCGA-L5-A43C-01A-11D-A247-09) from TCGA case TCGA-L5-A43C, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Lower third of esophagus; Tumor grade: GX; Age at diagnosis: 81.5 years (29,753 days).
Specimen TCGA-L5-A43C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a2c5694-f9d1-4876-9471-794efcbf8fe8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A43C-11A (Solid Tissue Normal), aliquot TCGA-L5-A43C-11A-11D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e81eadb-2747-45c6-befe-8276737f4ca6

The open-access MAF lists 139 somatic variants for this specimen: 103 protein-altering or splice-affecting, 29 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 29, Nonsense Mutation 8, Intron 4, Frame Shift Del 3, Splice Region 2, Splice Site 2, Frame Shift Ins 1, 3'Flank 1, 5'Flank 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP002748.5 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as rs786204444, CM031131; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- FBN1 | c.7742G>T p.C2581F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555394149, CM013942, CM077269; ClinVar: likely pathogenic; called by muse, mutect2
- SRSF2 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.57); PolyPhen benign (0.398); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC097636.1 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs572500189, COSV71309432; called by muse, mutect2, varscan2
- ADAMTS16 | c.3416C>T p.T1139M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs372733019; called by muse, mutect2
- BEND7 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs745972440, COSV61989162; called by muse, mutect2, varscan2
- CACNA1B | c.5402C>T p.T1801M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1208520621, COSV53152376; called by muse, mutect2, varscan2
- COL21A1 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs529924012, COSV55172945; called by muse, mutect2, varscan2
- COL6A3 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs776270797, COSV55083449; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCDC1 | c.544G>T p.G182* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs767557890; called by muse, mutect2, varscan2
- DPPA3 | c.372G>A p.K124= | Splice Region (SNP) | VAF 6/56 reads (11%) | catalogued as COSV61502887; called by muse, mutect2
- ELMO1 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs776057144, COSV100164366, COSV60302254, COSV99068342; called by muse, mutect2, varscan2
- EPHB2 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as rs750776222, COSV65862752, COSV65867179; called by muse, mutect2, varscan2
- FCRL3 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as COSV63841312; called by muse, mutect2, varscan2
- GABRA1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs763403354, COSV50099444; called by muse, mutect2, varscan2
- GRIK5 | c.2465C>T p.A822V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs982371304, COSV53483188; called by muse, mutect2, varscan2
- HAUS5 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs772550535; called by muse, mutect2, varscan2
- HSPG2 | c.12166G>C p.G4056R | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100760903; called by muse, mutect2, varscan2
- JARID2 | c.3145C>T p.R1049C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1005739215, COSV59200270; called by muse, mutect2
- MAST1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV52247150; called by muse, mutect2, varscan2
- MED1 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs770651048; called by muse, mutect2, varscan2
- NFKBID | c.370G>A p.V124M (on ENST00000396901; = p.V276M on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as rs769474042, COSV61728204; called by muse, mutect2, varscan2
- NPBWR1 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs776507864; called by muse, mutect2, varscan2
- OBSL1 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs774886081; called by muse, mutect2, varscan2
- OR10H5 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs1226439767; called by muse, mutect2
- OR10Z1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63525735; called by muse, mutect2
- OR51M1 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs751497394; called by muse, mutect2, varscan2
- PDCD11 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.394); catalogued as rs761396082; called by muse, mutect2, varscan2
- PKDREJ | c.5698G>T p.E1900* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV53547765; called by muse, mutect2
- PLCE1 | c.4570A>G p.M1524V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as rs764087748, CD1512228; called by muse, mutect2, varscan2
- POLD1 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs773665739, COSV70953996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLRMT | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs779119991; called by muse, mutect2, varscan2
- PXDN | c.2798G>A p.R933H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs766902490, COSV53246259; called by muse, mutect2, varscan2
- RBFOX1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.325); catalogued as rs199644500, COSV100300321, COSV60951913; called by muse, mutect2
- SDK1 | c.2405G>A p.R802H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs775673584, COSV67357448; called by muse, mutect2
- SPANXN3 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV65140338; called by muse, mutect2, varscan2
- SPEM1 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs758729774; called by muse, mutect2, varscan2
- THEG | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.649); catalogued as rs201450524; called by muse, mutect2, varscan2
- TOX2 | c.1358C>T p.P453L (on ENST00000358131 / NM_001098798.2; = p.P429L on NM_032883.3) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs758939019; called by muse, mutect2, varscan2
- TRPV1 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as rs917387664; called by muse, mutect2, varscan2
- TTC13 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs375164285; called by muse, mutect2, varscan2
- ZNF132 | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as rs370706847; called by muse, mutect2, varscan2
- ZNF385D | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1193540507, COSV55749808, COSV55756553; called by muse, mutect2, varscan2
- ADAM12 | c.1122G>T p.E374D | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM28 | c.769T>C p.W257R | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY1 | c.3264del p.V1089Cfs*50 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | called by mutect2, pindel, varscan2
- AFF1 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ALDH3A2 | c.1196T>A p.F399Y | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ATP8A1 | c.3035G>A p.W1012* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- CACNA1S | c.3874A>G p.I1292V | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.268); called by muse, mutect2
- CARTPT | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.098); called by muse, mutect2
- CASQ1 | c.1076T>A p.M359K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by mutect2, varscan2
- CCDC85A | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- CDK11B | c.1181G>C p.G394A | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.164); called by muse, mutect2
- CENPL | c.411T>A p.F137L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLASP1 | c.4445A>C p.K1482T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL6A3 | c.5093C>T p.T1698I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CORO7 | c.1280G>A p.G427D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CPA5 | c.1095C>A p.Y365* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- DENND2A | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- DOCK3 | c.3371G>T p.W1124L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DPY19L2 | c.2008A>G p.T670A | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- EIPR1 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ESPL1 | c.5721G>A p.M1907I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- FSIP1 | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNT10 | c.188T>G p.F63C | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2
- GPAT2 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR139 | c.131A>C p.N44T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- HECW2 | c.4591del p.I1531Sfs*30 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- ING2 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.148); called by muse, mutect2
- INTS10 | c.1834T>A p.C612S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- KDM4B | c.1788A>G p.A596= | Splice Region (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- KMT2B | c.5856_5861del p.P1953_T1954del | In Frame Del (DEL) | VAF 15/76 reads (20%) | called by mutect2, pindel, varscan2
- KMT2C | c.4818_4819dup p.M1607Kfs*59 | Frame Shift Ins (INS) | VAF 36/145 reads (25%) | called by mutect2, pindel, varscan2
- KSR2 | c.434A>G p.N145S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LAMA1 | c.1155+1G>A p.X385_splice | Splice Site (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- LAMA3 | c.2287C>A p.Q763K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MAPK6 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MBTD1 | c.1383A>C p.K461N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NBEAL2 | c.1966G>T p.V656L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- NUP160 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PANK2 | c.1209_1210del p.D403Efs*9 (on ENST00000316562 / NM_153638.3; = p.D112Efs*9 on NM_024960.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- PCDH17 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PCDHA12 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PCDHA8 | c.8A>G p.Y3C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA9 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PCNX3 | c.4930C>T p.R1644C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POLR1F | c.452T>A p.F151Y | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTCHD3 | c.2224A>G p.N742D | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.029); called by muse, mutect2
- RPS26 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- RPS6KA6 | c.1836T>G p.F612L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTN3 | c.1959C>A p.D653E (on ENST00000377819 / NM_001265589.2; = p.D634E on NM_201428.3) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SETD1A | c.1435A>T p.S479C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SGTA | c.497+1G>C p.X166_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- SLC44A3 | c.631G>A p.G211R (on ENST00000271227 / NM_001114106.3; = p.G163R on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.029); called by mutect2, varscan2
- SLC9A3 | c.1595T>C p.L532P | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBX21 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TIFAB | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTLL4 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- TTYH1 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- ZNF558 | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- ADAMTS10 | c.2379G>T p.P793= | Silent (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- ADCY10 | c.1434C>T p.C478= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2
- ANGPT4 | c.663G>A p.A221= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1477326685, COSV67922454; called by muse, mutect2, varscan2
- ATP11C | c.2107C>T p.L703= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs1377055029; called by muse, mutect2, varscan2
- CKS2 | c.93A>G p.Q31= | Silent (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- CMYA5 | c.643T>C p.L215= | Silent (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- DISC1 | c.660C>T p.A220= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs754450096; called by muse, mutect2, varscan2
- DNMT3A | c.2367C>T p.H789= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- FNDC1 | c.2412G>A p.T804= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs905549246; called by muse, mutect2, varscan2
- FZD2 | c.939C>T p.D313= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs775656853; called by muse, mutect2, varscan2
- GABRQ | c.438G>A p.L146= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs782359940; called by muse, mutect2, varscan2
- GRIK2 | c.1875G>A p.E625= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100029124; called by muse, mutect2, varscan2
- HGFAC | c.642C>T p.G214= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs762054716, COSV58748371, COSV58750573; called by muse, varscan2
- IL6R | c.894C>T p.F298= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs762649480, COSV59818301; called by muse, mutect2, varscan2
- IRAK2 | c.690C>T p.H230= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs372180328; called by muse, mutect2, varscan2
- IRGC | c.291G>A p.S97= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs11555892; called by muse, mutect2, varscan2
- KCNC3 | c.1557C>T p.V519= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs200349179; called by muse, mutect2, varscan2
- KLF7 | c.567G>A p.T189= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs758251787; called by muse, mutect2, varscan2
- LRIT1 | c.1761G>T p.L587= | Silent (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- MAP1B | c.42C>T p.S14= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- METTL17 | c.1056G>A p.A352= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs138028455; called by muse, mutect2, varscan2
- MYH7 | c.4774C>A p.R1592= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV62518877; called by mutect2, varscan2
- OR6N2 | c.564C>A p.A188= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100210447; called by muse, mutect2
- PRKCB | c.1530C>A p.P510= | Silent (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- SULF1 | c.672C>T p.P224= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs368146472; called by muse, mutect2, varscan2
- TTC13 | c.738G>A p.Q246= | Silent (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- VCAN | c.9159T>C p.T3053= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV54114557; called by muse, mutect2
- ZNF528 | c.1077C>T p.G359= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- ZNF835 | c.933C>T p.C311= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV73379544; called by muse, mutect2, varscan2
- CHM | c.1245-2449T>C | Intron (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- HTR4 | c.1077-982G>A | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- LRP12 | chr8:104484438 T>G | 3'Flank (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- MIR548I4 | n.53C>T | RNA (SNP) | VAF 14/35 reads (40%) | called by muse, varscan2
- RIMS2 | c.4064-21151C>T | Intron (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163856 C>G | 5'Flank (SNP) | VAF 32/180 reads (18%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-6216C>T | Intron (SNP) | VAF 9/94 reads (10%) | catalogued as rs765790629; called by muse, mutect2, varscan2
